CCDI case PBBTFZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/02086b04-48c3-434d-810e-1fda411a3513

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 10.5 years (3,833 days).

Biospecimens (3 samples)
- Sample 0DH5U7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH5VC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH5VP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
